Somatic mutation profile of tumor specimen MMRF_2830_1_BM_CD138pos (aliquot MMRF_2830_1_BM_CD138pos_T1_KHS5U_L16562) from MMRF case MMRF_2830, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.9 years (17,861 days).
Specimen MMRF_2830_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca9018da-4d7e-4def-96ad-2df9e8b4b6cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2830_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2830_1_PB_WBC_C2_KHS5U_L16605; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34f4c824-ec74-4974-ae0f-becf93448b96

The open-access MAF lists 95 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 23, Intron 12, Silent 10, 5'UTR 6, 5'Flank 6, RNA 2, Splice Region 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 46/99 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKAR | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs757357867, COSV55612940; called by muse, mutect2, varscan2
- BPIFB2 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.147); catalogued as rs201977178; called by muse, mutect2, varscan2
- CA12 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs747422711, COSV51604603; called by muse, mutect2, varscan2
- COL21A1 | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768012041; called by muse, mutect2, varscan2
- EEF1A1 | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV58548873, COSV58549955; called by muse, mutect2, varscan2
- EMC10 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.488); catalogued as rs1568686410; called by muse, mutect2, varscan2
- EPHA6 | c.3155C>T p.P1052L | Missense Mutation (SNP) | VAF 73/128 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs778168979, COSV67558533; called by muse, mutect2, varscan2
- EXTL3 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs370924429, COSV99593812; called by muse, mutect2, varscan2
- FREM1 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748464182, COSV66530345; called by muse, mutect2, varscan2
- GASK1A | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 133/204 reads (65%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs772364071, COSV56181841; called by muse, mutect2, varscan2
- IGHV2-70 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs72690597; called by muse, varscan2
- IGHV2-70 | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs370193821; called by muse, varscan2
- IGLL5 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 42/84 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs767386322, COSV73250551; called by muse, varscan2
- PRDM9 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs879146332; called by muse, mutect2, varscan2
- PSG7 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs531432163, COSV101343344; called by muse, mutect2, varscan2
- TRPM4 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs1314486531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSHZ3 | c.2662G>A p.A888T | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs547631684, COSV53668533; called by muse, mutect2, varscan2
- ZCCHC18 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62459520; called by muse, mutect2, varscan2
- ZNF672 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs1318723213; called by muse, mutect2
- ZNF862 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.808); catalogued as rs1017286153, COSV56223502; called by muse, mutect2, varscan2
- CCDC180 | c.275C>G p.A92G | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EMSY | c.2464C>A p.P822T | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- HERC1 | c.14572G>A p.D4858N | Missense Mutation (SNP) | VAF 127/207 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KBTBD4 | c.46T>G p.F16V | Missense Mutation (SNP) | VAF 110/173 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- KIAA1109 | c.3591G>A p.M1197I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1109 | c.13205C>T p.T4402I | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- LRP2 | c.12668T>C p.L4223P | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEA4 | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEA4 | c.844A>T p.T282S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCMBP | c.147A>C p.V49= | Splice Region (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- MYBPC1 | c.2455A>C p.S819R (on ENST00000550270 / NM_206820.2; = p.S826R on NM_002465.4) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P3H2 | c.1715G>A p.R572K | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- POLA1 | c.3276A>G p.G1092= | Splice Region (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- SDK2 | c.5482C>T p.P1828S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYN1 | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by mutect2, varscan2
- ADGRV1 | c.4455C>T p.S1485= | Silent (SNP) | VAF 91/273 reads (33%) | called by muse, mutect2, varscan2
- CLHC1 | c.87A>G p.R29= | Silent (SNP) | VAF 160/326 reads (49%) | called by muse, mutect2
- COL11A1 | c.4455A>G p.K1485= | Silent (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.78A>T p.P26= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as rs570281801; called by muse, varscan2
- LRRC4 | c.1209C>T p.V403= | Silent (SNP) | VAF 52/139 reads (37%) | catalogued as rs951063528; called by muse, mutect2, varscan2
- OLFML2B | c.141C>T p.N47= | Silent (SNP) | VAF 61/158 reads (39%) | catalogued as rs770352048, COSV54196407; called by muse, mutect2, varscan2
- OR1A1 | c.898C>A p.R300= | Silent (SNP) | VAF 48/213 reads (23%) | catalogued as rs138980523, COSV58404335; called by muse, mutect2, varscan2
- RYR1 | c.7161C>T p.S2387= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs766839127, COSV62113457; ClinVar: likely benign; called by muse, mutect2, varscan2
- SIGLEC1 | c.3702G>A p.R1234= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as COSV52460776, COSV99167597; called by muse, mutect2, varscan2
- ZNRF4 | c.750C>T p.P250= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as rs758882196; called by muse, mutect2, varscan2
- ABCA1 | c.*2697C>T | 3'UTR (SNP) | VAF 36/152 reads (24%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502859 G>A | 5'Flank (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- BBOX1 | c.*184A>G | 3'UTR (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021113 A>C | 5'Flank (SNP) | VAF 59/139 reads (42%) | catalogued as COSV55846424; called by muse, mutect2, varscan2
- C5orf64 | n.513-42935C>A | Intron (SNP) | VAF 22/77 reads (29%) | catalogued as rs1373807278; called by muse, mutect2, varscan2
- CCDC171 | c.*217A>G | 3'UTR (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- CCSAP | c.368-407T>A | Intron (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- CENPP | c.565-11103T>C | Intron (SNP) | VAF 58/108 reads (54%) | called by mutect2, varscan2
- CFAP52 | c.636+166C>T | Intron (SNP) | VAF 11/15 reads (73%) | catalogued as rs530704984; called by muse, mutect2, varscan2
- CHERP | c.-19G>A | 5'UTR (SNP) | VAF 32/138 reads (23%) | called by muse, varscan2
- COL11A1 | c.780+30C>T | Intron (SNP) | VAF 19/31 reads (61%) | catalogued as rs989794852, COSV62183921; called by muse, mutect2, varscan2
- CPLX2 | c.*3539C>T | 3'UTR (SNP) | VAF 66/191 reads (35%) | called by muse, mutect2, varscan2
- DERL2 | chr17:5486182 C>T | 5'Flank (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- DHDDS | c.*1840G>A | 3'UTR (SNP) | VAF 62/127 reads (49%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.2607C>T | RNA (SNP) | VAF 61/137 reads (45%) | catalogued as rs751539860; called by muse, mutect2, varscan2
- DTNA | c.1662+3100G>A | Intron (SNP) | VAF 35/74 reads (47%) | catalogued as rs984013148; called by muse, mutect2, varscan2
- EAF1 | c.*2247_*2249del | 3'UTR (DEL) | VAF 36/70 reads (51%) | called by mutect2, pindel, varscan2
- FP565260.6 | c.*2273A>G | 3'UTR (SNP) | VAF 3/34 reads (9%) | catalogued as rs1466789100; called by muse, mutect2
- FRAS1 | c.109-55564G>A | Intron (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- GNAQ | c.*4283G>C | 3'UTR (SNP) | VAF 51/90 reads (57%) | called by muse, mutect2, varscan2
- GPR107 | c.-12G>A | 5'UTR (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- HSP90B1 | c.1230+41dup | Intron (INS) | VAF 28/63 reads (44%) | called by mutect2, pindel, varscan2
- IGLL5 | c.-82C>G | 5'UTR (SNP) | VAF 30/71 reads (42%) | catalogued as rs145026872, COSV104440301; called by muse, varscan2
- KHNYN | c.*2626T>C | 3'UTR (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- KRT6A | c.*6G>A | 3'UTR (SNP) | VAF 30/65 reads (46%) | catalogued as rs200885123; called by muse, mutect2, varscan2
- LRATD2 | c.*3910C>T | 3'UTR (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- LRRC72 | c.-45C>T | 5'UTR (SNP) | VAF 42/120 reads (35%) | catalogued as rs1382440994; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851315 C>T | 5'Flank (SNP) | VAF 65/151 reads (43%) | catalogued as rs537569481; called by muse, mutect2, varscan2
- ONECUT1 | c.1105+7835A>C | Intron (SNP) | VAF 39/70 reads (56%) | called by muse, varscan2
- PABPC5 | c.*1363A>C | 3'UTR (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- PIK3CB | c.*1355C>T | 3'UTR (SNP) | VAF 31/49 reads (63%) | catalogued as rs910401117; called by muse, mutect2, varscan2
- PITHD1 | c.*241G>A | 3'UTR (SNP) | VAF 54/100 reads (54%) | called by muse, mutect2, varscan2
- PLCG2 | chr16:81785961 T>A | 5'Flank (SNP) | VAF 46/147 reads (31%) | called by muse, mutect2, varscan2
- RNF44 | c.1136+28C>T | Intron (SNP) | VAF 38/121 reads (31%) | catalogued as rs377329879; called by muse, mutect2, varscan2
- RRM2B | c.-45G>A | 5'UTR (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- SAV1 | c.*481A>T | 3'UTR (SNP) | VAF 6/23 reads (26%) | called by muse, varscan2
- SAV1 | c.*432A>C | 3'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, varscan2
- SH2D4A | c.-274C>A | 5'UTR (SNP) | VAF 14/49 reads (29%) | catalogued as COSV56123914; called by muse, varscan2
- SLC26A5 | c.*54_*55del | 3'UTR (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- SLC2A2 | c.*133T>A | 3'UTR (SNP) | VAF 43/113 reads (38%) | called by muse, mutect2, varscan2
- SPATA8 | n.988C>T | RNA (SNP) | VAF 69/253 reads (27%) | catalogued as COSV100138883; called by muse, mutect2, varscan2
- SPRR3 | c.*228G>A | 3'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- SREBF1 | c.2736-53G>A | Intron (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- SYBU | c.*430A>T | 3'UTR (SNP) | VAF 46/92 reads (50%) | called by muse, varscan2
- TADA2B | c.271-108G>A | Intron (SNP) | VAF 3/36 reads (8%) | catalogued as rs1240137645; called by muse, mutect2
- TALDO1 | chr11:747449 C>A | 5'Flank (SNP) | VAF 20/186 reads (11%) | called by mutect2, varscan2
- TIE1 | c.*266C>T | 3'UTR (SNP) | VAF 81/192 reads (42%) | catalogued as rs968492102; called by muse, mutect2, varscan2
- TRIM7 | c.*1225C>G | 3'UTR (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- WBP1L | c.*58C>T | 3'UTR (SNP) | VAF 63/168 reads (38%) | catalogued as rs750678879; called by muse, mutect2, varscan2
